CCDI case PBBNPJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/9d16d45c-14fa-4d08-b703-9f022db92eff

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 12.3 years (4,510 days).

Biospecimens (3 samples)
- Sample 0DDZK1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DDZK4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEK0Z: Tissue type: Tumor; Specimen type: Solid Tissue.
